Gene-level copy-number profile of tumor specimen TCGA-29-1691-01A from TCGA case TCGA-29-1691, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 51.1 years (18,664 days).
Specimen TCGA-29-1691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4f153dda-e919-4502-aa9f-0d52487e60eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1691-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/61c04941-8cfc-44cd-a277-c3dae87d6c53

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 1,838; copy number 2: 17,016; copy number 3: 18,808; copy number 4: 14,496; copy number 5: 5,194; copy number 6: 1,111; copy number 7: 563; copy number 8: 379; copy number 9: 350; copy number 10: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1691-01A-01D-0559-01): tumor purity 0.91, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:72,996,803–73,069,198, 2 genes (within-gene range 0–2): PPP4R2, RNU7-19P.
- chr4:147,732,063–148,072,776, 1 gene (within-gene range 0–5): ARHGAP10.
- chr4:147,916,529–149,896,233, 17 genes (within-gene range 0–2): AC115621.1, NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355, IQCM, AC108168.1, AC093893.1.
- chr5:111,662,621–111,997,464, 3 genes (within-gene range 0–1): NREP, RN7SKP57, HMGN1P14.
- chr15:32,765,544–33,194,714, 1 gene (within-gene range 0–1): FMN1.
- chr15:32,970,727–34,075,155, 15 genes (within-gene range 0–1): AC018515.1, HNRNPA1P71, AC019278.1, TMCO5B, AC055874.1, RYR3, Y_RNA, AC010809.3, AC010809.2, AC010809.1, AVEN, CHRM5, AC009268.2, AC009268.3, AC009268.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,304 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:139,935,185–182,035,644, 624 genes, copy number 7–9 (within-gene range 3–9) (broad region; genes not listed).
- chr5:58,198–2,967,955, 86 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr6:18,363,417–25,930,726, 109 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr12:44,498,616–46,972,155, 37 genes, copy number 7: AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1.
- chr15:95,638,316–101,933,350, 149 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr19:33,386,950–39,476,670, 299 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,528. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
